Somatic mutation profile of tumor specimen TCGA-VR-A8EW-01A (aliquot TCGA-VR-A8EW-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.2 years (20,902 days).
Specimen TCGA-VR-A8EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fec4241-34aa-4aae-9046-4df4989a776d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EW-10A (Blood Derived Normal), aliquot TCGA-VR-A8EW-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb275003-1b0c-4310-8373-4d7bd49a3f72

The open-access MAF lists 111 somatic variants for this specimen: 86 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 24, Nonsense Mutation 5, Splice Site 3, Frame Shift Ins 1, Intron 1, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/198 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP30 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752547354, COSV63517707; called by muse, mutect2, varscan2
- ATP10A | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1250531615, COSV100791668; called by muse, mutect2, varscan2
- C1orf74 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs748935585; called by muse, mutect2, varscan2
- COL6A3 | c.9316C>T p.L3106F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs112455407; called by muse, mutect2, varscan2
- DCTD | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as rs764782245, COSV63866968; called by muse, mutect2, varscan2
- FCGR3A | c.167A>C p.N56T | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as COSV100914644; called by muse, mutect2
- FCGR3B | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV54209568; called by muse, mutect2
- GRID2 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.95); catalogued as COSV99944491; called by muse, mutect2, varscan2
- HDAC9 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101286812, COSV67769445; called by muse, mutect2, varscan2
- HERC1 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs377537305; called by muse, mutect2, varscan2
- HTR1F | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.034); catalogued as rs1251229337; called by muse, mutect2, varscan2
- ITPRIP | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs746792406, COSV53392991; called by muse, mutect2, varscan2
- MEGF8 | c.7838A>T p.Y2613F (on ENST00000251268 / NM_001271938.2; = p.Y2546F on NM_001410.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs766724451; called by muse, mutect2, varscan2
- MFAP3L | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100852693; called by muse, mutect2
- MGA | c.8536G>A p.E2846K (on ENST00000219905 / NM_001164273.1; = p.E2637K on NM_001080541.2) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54958138; called by muse, mutect2, varscan2
- MLLT10 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57005367, COSV57005643; called by muse, mutect2, varscan2
- NFATC4 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs920557882, COSV51598742; called by muse, mutect2, varscan2
- NOS1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380658814, COSV57622541; called by muse, mutect2, varscan2
- PNOC | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs1421822819; called by muse, mutect2, varscan2
- PTCH1 | c.1348-2A>T p.X450_splice | Splice Site (SNP) | VAF 38/44 reads (86%) | catalogued as CS127979; called by muse, mutect2, varscan2
- PTPRT | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs868706902, COSV62004992; called by muse, mutect2, varscan2
- RABGAP1L | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52290841; called by muse, mutect2, varscan2
- RER1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60384316; called by muse, mutect2, varscan2
- RIMS2 | c.4291C>T p.R1431C (on ENST00000666250 / NM_001348490.2; = p.R1002C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763285258, COSV51660936; called by muse, mutect2, varscan2
- SHANK2 | c.5242C>T p.P1748S | Missense Mutation (SNP) | VAF 29/724 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as rs370834280; called by muse, mutect2
- STXBP5L | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs745826307; called by muse, mutect2, varscan2
- TRMT10C | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59306778; called by muse, mutect2
- TTBK1 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1392098579; called by muse, mutect2, varscan2
- UBR4 | c.7192G>A p.D2398N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs55848569, COSV100920959; called by mutect2, varscan2
- UTP3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as rs780006978, COSV54661415; called by muse, mutect2, varscan2
- YTHDF3 | c.1719_1721del p.E574del | In Frame Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs753684267; called by pindel, varscan2
- YWHAG | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV56899860; called by muse, mutect2, varscan2
- ACE | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.415); called by muse, mutect2
- AFAP1L2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- AFF1 | c.1394A>G p.H465R | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- AP4E1 | c.1906G>C p.G636R | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP7B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP8B1 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAIAP2L1 | c.891G>T p.L297F | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CA1 | c.470A>T p.K157M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CBLB | c.1715G>C p.S572T | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2
- CLEC4M | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- COL16A1 | c.1633A>T p.I545F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CTNNA2 | c.1985T>A p.L662H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EIF2B1 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- GNL1 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPRASP1 | c.3385C>G p.L1129V | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFT122 | c.2291C>A p.P764H (on ENST00000348417 / NM_052989.3; = p.P705H on NM_018262.4) | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHG1 | c.455A>G p.E152G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- IRS4 | c.3499G>T p.A1167S | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- KIAA2026 | c.1983_2001del p.R661Sfs*11 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- KLF10 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- KRT33B | c.876G>T p.L292= | Splice Region (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- KTN1 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2
- LRRC37A2 | c.4884G>A p.W1628* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- MAP3K1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDNF | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | called by muse, varscan2
- NOP10 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NOP10 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PDHA2 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGLYRP1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PHF8 | c.761A>G p.N254S (on ENST00000357988 / NM_001184896.1; = p.N218S on NM_015107.3) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNPO | c.71A>G p.H24R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF6 | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PRF1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCA | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- PSMA6 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RABGAP1L | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- RPN2 | c.1770G>T p.M590I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SDHAF4 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SEMA3A | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC39A8 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SP140L | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- SPAG1 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNE2 | c.18751G>C p.E6251Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TBXA2R | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.2354T>G p.L785R (on ENST00000355622 / NM_138554.5; = p.L745R on NM_003266.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM47 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- TRIM9 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 97/158 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UGGT1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UTS2B | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- VSIG10 | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.15); called by muse, mutect2
- WDSUB1 | c.901dup p.M301Nfs*11 | Frame Shift Ins (INS) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.3575A>C p.N1192T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by mutect2, varscan2
- ALDH1B1 | c.648C>G p.L216= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV66619671; called by muse, mutect2, varscan2
- CRAMP1 | c.2844G>A p.T948= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as rs753839016; called by muse, mutect2, varscan2
- DNAH7 | c.3375A>G p.V1125= | Silent (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- GET3 | c.378C>T p.S126= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV62003033; called by muse, mutect2, varscan2
- LAMB1 | c.285C>T p.L95= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- MED19 | c.369T>C p.D123= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- MMRN2 | c.2295C>T p.N765= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1210396871; called by muse, mutect2, varscan2
- MORN1 | c.816C>A p.V272= | Silent (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- MTCH1 | c.1113A>T p.R371= (on ENST00000373627 / NM_001271641.1; = p.R354= on NM_014341.2) | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1038C>T p.Y346= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs769202397; called by muse, mutect2, varscan2
- OR2L8 | c.162C>A p.L54= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV61728323; called by muse, mutect2, varscan2
- OTOGL | c.6882C>T p.D2294= (on ENST00000547103; = p.D2285= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs751285103; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH15 | c.4789C>T p.L1597= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- RALGPS2 | c.372T>C p.Y124= | Silent (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- RASGRP1 | c.177A>T p.G59= | Silent (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- RIN1 | c.1990C>A p.R664= | Silent (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- SPATA18 | c.73C>T p.L25= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV54647126; called by muse, mutect2, varscan2
- SPATA31D1 | c.2013C>A p.S671= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- SPO11 | c.36C>T p.F12= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs919931130; called by muse, mutect2, varscan2
- TREML2 | c.51C>T p.V17= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1445531952; called by muse, varscan2
- UNC45A | c.1281C>T p.D427= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs949088045, COSV67817547; called by muse, mutect2, varscan2
- USH2A | c.346C>T p.L116= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- UTP3 | c.438A>T p.R146= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8721G>A p.P2907= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs773478219, COSV50690055; called by muse, mutect2, varscan2
- PCDHA8 | c.2394+23C>A | Intron (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
